Gene-level copy-number profile of specimen HCM-BROD-0196-C71-85A from HCMI case HCM-BROD-0196-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 59.9 years (21,887 days).
Specimen HCM-BROD-0196-C71-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 10.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e984a970-2baf-4342-a619-3f447010c806.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0196-C71-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,718 have no estimate.
https://portal.gdc.cancer.gov/files/89903cf1-d528-497c-8c6d-b06211308831

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 24; copy number 1: 8,832; copy number 2: 47,233; copy number 3: 2,816.

Homozygous deletions (total copy number 0; autosomes only): 24 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr15:20,657,638–20,756,183, 4 genes: NBEAP1, AC131280.1, AC012414.4, RNU6-498P.
- chr15:21,010,494–21,260,147, 13 genes: IGHD5OR15-5B, IGHD4OR15-4B, IGHD3OR15-3B, IGHD2OR15-2B, IGHD1OR15-1B, FAM30C, AC037471.1, BCAR1P2, RN7SL400P, AC126335.1, AC126335.2, BMS1P16, NBEAP4.
- chr15:32,406,597–32,461,809, 6 genes (within-gene range 0–1): ULK4P1, U8, DNM1P32, GOLGA8O, RN7SL539P, AC135983.5.
- chr22:18,650,023–18,653,617, 1 gene: PPP1R26P2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 5,976. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
